MMRF case MMRF_1608 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7da8e250-ea31-4fb2-abc7-d1b1d27113cf

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.3 years (22,392 days); ISS stage: II; Days to last known disease status: 1,269 days (3.5 years); Days to last follow up: 1,269 days (3.5 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 398 days (1.1 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days; Days to treatment end: 56 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 56 days; Days to treatment end: 398 days (1.1 years).
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 399 days (1.1 years); Days to treatment end: 539 days (1.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 540 days (1.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 1): M Protein 5.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 111 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.06 mg/dL; Immunoglobulin G 81.7 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 4.6 µg/mL; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.6 mmol/L; Albumin 32 g/L; Total Protein 11.3 g/dL; Glucose 6.55 mmol/L; C-Reactive Protein 0.477 mg/dL.
- Day 84: M Protein 3.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 90.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.05 mg/dL; Immunoglobulin G 48.3 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 353 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 32 g/L; Total Protein 8.9 g/dL; Glucose 5.12 mmol/L.
- Day 168: M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 28.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.04 mg/dL; Immunoglobulin G 27.7 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 411 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.08 mmol/L; Albumin 33 g/L; Total Protein 6.9 g/dL; Glucose 5.23 mmol/L.
- Day 273 (ECOG 1): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 23.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 20.9 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 32 g/L; Total Protein 6.5 g/dL; Glucose 4.51 mmol/L.
- Day 356 (ECOG 1): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 20.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.05 mg/dL; Immunoglobulin G 18.8 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 3.93 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 7.3 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.15 mmol/L; Albumin 31 g/L; Total Protein 5.8 g/dL; Glucose 5.61 mmol/L.
- Day 456 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.71 mg/dL; Immunoglobulin G 6.37 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 458 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 5.6 g/dL; Glucose 5.39 mmol/L.
- Day 540 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 5.15 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 281 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 5.8 g/dL; Glucose 5.23 mmol/L.
- Day 624: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 8.13 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 5.5 mmol/L.
- Day 722 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.2 mg/dL; Immunoglobulin G 7.78 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 4.46 mmol/L.
- Day 820 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 9.6 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 258 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 5.06 mmol/L.
- Day 904 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.88 mg/dL; Immunoglobulin G 9.37 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 3.58 mmol/L.
- Day 988 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.84 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 243 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 5.01 mmol/L.
- Day 1,107 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 0.9 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 4.18 mmol/L.
- Day 1,184 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.77 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 4.95 mmol/L.
- Day 1,269 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 14 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 262 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 7.2 g/dL; Glucose 5.45 mmol/L.

Other clinical attributes
- Day -4: Weight: 90 kg; Height: 168 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1608_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_1608_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
